Somatic mutation profile of tumor specimen 0DD6QV from CCDI case PBBNMV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.9 years (2,890 days).
Specimen 0DD6QV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 027890ac-234e-40db-8f7b-d54ffe9948b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DD6QW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33f1b7f2-0007-4e6a-8e5e-bd6830876c03

The open-access MAF lists 48 somatic variants for this specimen: 34 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 8, Intron 3, Nonsense Mutation 1, 3'Flank 1, Splice Site 1, 3'UTR 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 305/422 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52666332, COSV52700326, COSV52746468; called by muse, mutect2, varscan2
- AMPD2 | c.1036G>C p.A346P | Missense Mutation (SNP) | VAF 60/736 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV56647354; called by muse, mutect2
- CCDC141 | c.4523G>C p.R1508T | Missense Mutation (SNP) | VAF 285/1098 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV55375622; called by muse, mutect2, varscan2
- CMKLR1 | c.742C>A p.Q248K (on ENST00000312143 / NM_001142344.2; = p.Q246K on NM_004072.3) | Missense Mutation (SNP) | VAF 221/557 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1183875678; called by muse, mutect2, varscan2
- L3MBTL3 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 29/1082 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1420387654; called by muse, mutect2
- MFSD6L | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1040950680; called by muse, mutect2, varscan2
- MGAT5B | c.618G>T p.W206C | Missense Mutation (SNP) | VAF 182/586 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.855); catalogued as COSV56934329; called by muse, mutect2, varscan2
- NPBWR2 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 140/406 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs778749703, COSV100871164; called by muse, mutect2, varscan2
- PITPNB | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 24/518 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV58062220; called by muse, mutect2
- RPGRIP1 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 63/380 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as COSV52849828; called by muse, mutect2, varscan2
- ZGLP1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 204/408 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV67059222; called by muse, mutect2, varscan2
- ABCC9 | c.4037G>T p.G1346V | Missense Mutation (SNP) | VAF 19/579 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRD36C | c.557A>G p.K186R | Missense Mutation (SNP) | VAF 30/1246 reads (2%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.631); called by muse, mutect2
- ATP8B3 | c.300C>G p.D100E | Missense Mutation (SNP) | VAF 70/719 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- CEP350 | c.4456C>T p.P1486S | Missense Mutation (SNP) | VAF 53/759 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CNKSR2 | c.2833G>T p.D945Y | Missense Mutation (SNP) | VAF 35/908 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPA6 | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 40/934 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2
- CR1 | c.3751C>G p.P1251A | Missense Mutation (SNP) | VAF 286/731 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DERL1 | c.114C>G p.Y38* | Nonsense Mutation (SNP) | VAF 34/1030 reads (3%) | called by muse, mutect2
- DNAH3 | c.9893C>T p.A3298V | Missense Mutation (SNP) | VAF 189/459 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- IL1R2 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 250/1051 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KIAA2026 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- MAGEB18 | c.650A>G p.E217G | Missense Mutation (SNP) | VAF 288/677 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MAP2K4 | c.813+1G>C p.X271_splice | Splice Site (SNP) | VAF 36/313 reads (12%) | called by muse, mutect2, varscan2
- MUC5AC | c.7174C>T p.P2392S | Missense Mutation (SNP) | VAF 154/429 reads (36%) | SIFT tolerated (0.22); called by muse, varscan2
- PCSK4 | c.660_666dup p.N223Rfs*311 | Frame Shift Ins (INS) | VAF 120/398 reads (30%) | called by mutect2, varscan2
- PLA2R1 | c.1499T>A p.I500N | Missense Mutation (SNP) | VAF 32/1167 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- PPP1R13B | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 145/343 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTCH2 | c.2029G>T p.A677S | Missense Mutation (SNP) | VAF 362/865 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RFC1 | c.2890G>T p.G964W (on ENST00000381897 / NM_001363496.2; = p.G963W on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/640 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC6A1 | c.376G>C p.G126R | Missense Mutation (SNP) | VAF 98/248 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SLITRK4 | c.602A>C p.H201P | Missense Mutation (SNP) | VAF 27/732 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SUGP1 | c.1744G>A p.G582S | Missense Mutation (SNP) | VAF 260/712 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM117 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 29/713 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- C15orf39 | c.2754C>T p.R918= | Silent (SNP) | VAF 154/638 reads (24%) | catalogued as rs146637741; called by muse, mutect2, varscan2
- CADM2 | c.576G>T p.V192= (on ENST00000407528 / NM_001167674.2; = p.V194= on NM_153184.4) | Silent (SNP) | VAF 201/664 reads (30%) | catalogued as rs750266974; called by muse, mutect2, varscan2
- GUCY2D | c.1062C>A p.V354= | Silent (SNP) | VAF 416/511 reads (81%) | called by muse, mutect2, varscan2
- OR4C15 | c.603C>A p.A201= (on ENST00000314644; = p.A147= on NM_001001920.2) | Silent (SNP) | VAF 94/235 reads (40%) | catalogued as rs745778808; called by muse, mutect2, varscan2
- SORBS1 | c.3759C>T p.R1253= (on ENST00000361941 / NM_001034954.2; = p.R645= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 273/383 reads (71%) | catalogued as rs757957966; called by muse, mutect2, varscan2
- SUPV3L1 | c.381T>C p.F127= | Silent (SNP) | VAF 280/499 reads (56%) | catalogued as rs565904074; called by muse, varscan2
- TMEM255A | c.705G>T p.L235= | Silent (SNP) | VAF 414/926 reads (45%) | called by muse, mutect2, varscan2
- USO1 | c.528G>A p.A176= | Silent (SNP) | VAF 34/613 reads (6%) | catalogued as rs755649204; called by muse, mutect2
- CYGB | c.-80C>T | 5'UTR (SNP) | VAF 78/230 reads (34%) | called by muse, mutect2, varscan2
- MAPKAPK2 | c.893-26T>C | Intron (SNP) | VAF 51/119 reads (43%) | called by muse, mutect2, varscan2
- MCF2L | chr13:113096931 C>T | 3'Flank (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- PPAN | c.19-32C>G | Intron (SNP) | VAF 159/340 reads (47%) | called by muse, mutect2, varscan2
- SFXN5 | c.171+47G>T | Intron (SNP) | VAF 172/530 reads (32%) | called by muse, mutect2, varscan2
- SLFN12L | c.*17C>G | 3'UTR (SNP) | VAF 105/388 reads (27%) | called by muse, mutect2, varscan2
